Somatic mutation profile of tumor specimen TARGET-10-PAPEMC-09A (aliquot TARGET-10-PAPEMC-09A-01D) from TARGET case TARGET-10-PAPEMC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (962 days).
Specimen TARGET-10-PAPEMC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89cf95b7-d7b6-42da-8ac0-d3bd9fc20667.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPEMC-14A (Bone Marrow Normal), aliquot TARGET-10-PAPEMC-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7bb4c961-5504-4676-8a75-7852c1c962b8

The open-access MAF lists 27 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 6, Intron 5, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.2132G>T p.R711I (on ENST00000272895 / NM_173076.3; = p.R393I on NM_015657.3) | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as COSV55977561; called by muse, mutect2
- CACNA1F | c.769G>T p.E257* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV59906692; called by muse, mutect2
- DLC1 | c.3006G>T p.W1002C (on ENST00000276297 / NM_001348081.2; = p.W565C on NM_006094.5) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52291397; called by muse, mutect2, varscan2
- SLC14A2 | c.32C>A p.P11Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.047); catalogued as rs1418491674; called by muse, mutect2
- TINAG | c.923C>A p.P308Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52515713; called by muse, varscan2
- TRPC7 | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV61458478, COSV61460402; called by muse, mutect2, varscan2
- TTN | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 48/135 reads (36%) | PolyPhen probably damaging (0.962); catalogued as rs772248060, COSV60229592, COSV60419932; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HNRNPF | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- KIAA1841 | c.2039G>C p.G680A | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- KMT2A | c.10457C>A p.T3486K | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.09); called by muse, mutect2
- MON2 | c.661C>A p.Q221K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); called by muse, mutect2
- PBRM1 | c.1563G>T p.Q521H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by mutect2, varscan2
- PKD1L1 | c.6583G>T p.A2195S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.038); called by muse, varscan2
- TBL3 | c.1418C>A p.T473N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.116); called by muse, varscan2
- TNRC18 | c.1848G>T p.L616F | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- UFSP2 | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.03); called by muse, mutect2
- ACO2 | c.1285C>A p.R429= | Silent (SNP) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- ATG2A | c.1956G>T p.L652= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2, varscan2
- HADH | c.492C>T p.D164= | Silent (SNP) | VAF 58/226 reads (26%) | called by muse, mutect2, varscan2
- LHX9 | c.150C>A p.G50= | Silent (SNP) | VAF 4/19 reads (21%) | called by mutect2, varscan2
- NPY2R | c.1014G>A p.S338= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs762321154, COSV61528197; called by muse, varscan2
- OLFML2A | c.1644C>A p.I548= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs372227389, COSV56583021; called by mutect2, varscan2
- ABCC8 | c.3989-27G>T | Intron (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- HSF1 | c.1314+14C>T | Intron (SNP) | VAF 35/53 reads (66%) | catalogued as rs782512036; called by muse, mutect2, varscan2
- KDM2A | c.1480-2655C>A | Intron (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
- KDM5D | c.2583+171G>T | Intron (SNP) | VAF 4/42 reads (10%) | called by muse, varscan2
- RNF212 | c.247-2792G>T | Intron (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
